Gene-level copy-number profile of specimen HCM-BROD-0420-C71-85R from HCMI case HCM-BROD-0420-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.3 years (17,653 days).
Specimen HCM-BROD-0420-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e616243e-37ae-459e-93d2-9dc596ce172f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0420-C71-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,854 have no estimate.
https://portal.gdc.cancer.gov/files/ba629150-c24e-43ad-9f05-82466c14fd09

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 14,164; copy number 2: 39,028; copy number 3: 5,569.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 11,460. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
